Somatic mutation profile of tumor specimen MP2PRT-PASJFM-TMP1-A (aliquot MP2PRT-PASJFM-TMP1-A-1-0-D-A81N-36) from MP2PRT case MP2PRT-PASJFM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Subacute lymphoid leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.1 years (2,952 days).
Specimen MP2PRT-PASJFM-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d441b71f-ce5b-4c1e-b883-578de8def50f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASJFM-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASJFM-NB1-A-1-0-D-A81N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ac0783df-37ae-423b-906a-e211b1d9214a

The open-access MAF lists 62 somatic variants for this specimen: 47 protein-altering or splice-affecting, 13 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 13, Nonsense Mutation 4, 5'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SF3B1 | c.1998G>C p.K666N | Missense Mutation (SNP) | VAF 84/336 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs377023736, COSV59205777, COSV59205799; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AATF | c.1420C>T p.R474W | Missense Mutation (SNP) | VAF 233/541 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs760234359; called by muse, mutect2, varscan2
- ADAM18 | c.2195C>G p.S732* | Nonsense Mutation (SNP) | VAF 27/238 reads (11%) | catalogued as COSV55854999; called by muse, mutect2, varscan2
- APBA2 | c.1990C>T p.R664W | Missense Mutation (SNP) | VAF 42/600 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1163175260; called by muse, mutect2
- ARID1B | c.3082G>A p.E1028K | Missense Mutation (SNP) | VAF 31/480 reads (6%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.955); catalogued as rs570798143; called by muse, mutect2
- BEND3 | c.1719C>A p.F573L | Missense Mutation (SNP) | VAF 82/549 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV64682257; called by muse, mutect2, varscan2
- DCLK1 | c.1979C>T p.S660L | Missense Mutation (SNP) | VAF 61/402 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.071); catalogued as COSV55188698; called by muse, mutect2, varscan2
- EIF2S3 | c.43C>G p.L15V | Missense Mutation (SNP) | VAF 45/323 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV53408139; called by muse, mutect2, varscan2
- GRAMD1B | c.721G>A p.D241N | Missense Mutation (SNP) | VAF 59/367 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.434); catalogued as rs895281458, COSV100455381; called by muse, mutect2, varscan2
- KCNQ4 | c.1474C>T p.R492W | Missense Mutation (SNP) | VAF 212/552 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1371296507; called by muse, mutect2, varscan2
- LENG8 | c.938C>T p.T313M | Missense Mutation (SNP) | VAF 210/887 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs750220608, COSV58727365, COSV58727682; called by muse, mutect2, varscan2
- LILRB5 | c.1348C>T p.P450S (on ENST00000449561 / NM_001081442.3; = p.P449S on NM_006840.5) | Missense Mutation (SNP) | VAF 37/753 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs1351456242; called by muse, mutect2
- LMTK2 | c.706G>A p.D236N | Missense Mutation (SNP) | VAF 52/912 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.069); catalogued as rs771058238; called by muse, mutect2
- MYO18A | c.890G>A p.R297Q | Missense Mutation (SNP) | VAF 117/479 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs777618687; called by muse, mutect2, varscan2
- PCDHA3 | c.263C>T p.S88F | Missense Mutation (SNP) | VAF 106/686 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.612); catalogued as rs1231634560, COSV100974156; called by muse, mutect2, varscan2
- PCDHAC1 | c.2341C>T p.R781* | Nonsense Mutation (SNP) | VAF 197/508 reads (39%) | catalogued as rs782744711, COSV53858986; called by muse, mutect2, varscan2
- PPP2R2B | c.556G>A p.E186K (on ENST00000394409; = p.E252K on NM_181674.2) | Missense Mutation (SNP) | VAF 38/587 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.832); catalogued as COSV60765231; called by muse, mutect2
- RAB40AL | c.310G>A p.G104S | Missense Mutation (SNP) | VAF 8/275 reads (3%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs1410918032; called by muse, mutect2
- SECISBP2L | c.2444G>C p.R815T (on ENST00000559471 / NM_001193489.2; = p.R770T on NM_014701.4) | Missense Mutation (SNP) | VAF 73/331 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99961064; called by muse, mutect2, varscan2
- SH2D3C | c.2545C>A p.H849N (on ENST00000314830 / NM_170600.3; = p.H692N on NM_005489.4) | Missense Mutation (SNP) | VAF 48/601 reads (8%) | SIFT tolerated (0.54); PolyPhen benign (0.052); catalogued as COSV59128424; called by muse, mutect2
- TEX264 | c.766G>A p.D256N | Missense Mutation (SNP) | VAF 36/672 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as COSV56587789; called by muse, mutect2
- THBS2 | c.1181C>T p.S394F | Missense Mutation (SNP) | VAF 42/899 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV64680065; called by muse, mutect2
- TPR | c.5887G>T p.E1963* | Nonsense Mutation (SNP) | VAF 10/212 reads (5%) | catalogued as COSV66599051, COSV66602432; called by muse, mutect2
- WDR87 | c.8471C>T p.A2824V | Missense Mutation (SNP) | VAF 156/430 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs372915097; called by muse, mutect2, varscan2
- ABCA4 | c.6704C>T p.S2235L | Missense Mutation (SNP) | VAF 110/255 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- ABI3BP | c.61G>T p.A21S | Missense Mutation (SNP) | VAF 34/312 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- ADAM28 | c.1670A>G p.N557S | Missense Mutation (SNP) | VAF 109/290 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ANKS1B | c.3385G>C p.E1129Q (on ENST00000547776 / NM_152788.4; = p.E295Q on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/408 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- ARHGAP31 | c.1348A>G p.M450V | Missense Mutation (SNP) | VAF 233/576 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CHFR | c.1754G>C p.G585A (on ENST00000432561 / NM_001161345.1; = p.G544A on NM_018223.2) | Missense Mutation (SNP) | VAF 12/336 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DMBT1 | c.5071G>T p.A1691S (on ENST00000338354 / NM_001377530.1; = p.A934S on NM_004406.3) | Missense Mutation (SNP) | VAF 214/673 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DOCK4 | c.3841G>C p.E1281Q | Missense Mutation (SNP) | VAF 77/320 reads (24%) | SIFT tolerated (0.58); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- FAT3 | c.3683A>G p.D1228G | Missense Mutation (SNP) | VAF 106/265 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FGFR3 | c.211C>A p.P71T | Missense Mutation (SNP) | VAF 250/698 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, varscan2
- GPR156 | c.1606G>A p.E536K | Missense Mutation (SNP) | VAF 28/608 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2
- IGHV4-61 | chr14:106639113 ACTGTGTCT>GGAGA | Missense Mutation (DEL) | VAF 66/284 reads (23%) | called by pindel, varscan2*
- ITPRID1 | c.2369C>T p.S790F | Missense Mutation (SNP) | VAF 24/610 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.127); called by muse, mutect2
- MAST2 | c.2404C>T p.P802S | Missense Mutation (SNP) | VAF 19/332 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- MR1 | c.523C>G p.Q175E | Missense Mutation (SNP) | VAF 145/402 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- OR8H1 | c.359A>T p.D120V | Missense Mutation (SNP) | VAF 64/474 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDAP1 | c.172C>G p.L58V | Missense Mutation (SNP) | VAF 21/438 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.026); called by muse, mutect2
- SPINK5 | c.419G>A p.G140E | Missense Mutation (SNP) | VAF 31/327 reads (9%) | SIFT tolerated (0.82); PolyPhen benign (0.232); called by muse, mutect2
- TFDP3 | c.389G>C p.C130S | Missense Mutation (SNP) | VAF 352/445 reads (79%) | SIFT tolerated (0.06); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- THAP5 | c.629C>G p.S210* (on ENST00000415914 / NM_001130475.3; = p.S168* on NM_182529.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 39/116 reads (34%) | called by muse, mutect2, varscan2
- TOR2A | c.16C>T p.R6C | Missense Mutation (SNP) | VAF 43/803 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2
- UBA2 | c.770A>T p.K257M | Missense Mutation (SNP) | VAF 53/144 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ZNF717 | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 42/403 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATXN7L2 | c.1290C>T p.R430= | Silent (SNP) | VAF 33/620 reads (5%) | catalogued as COSV60205558; called by muse, mutect2
- CADPS2 | c.2529G>T p.L843= | Silent (SNP) | VAF 93/398 reads (23%) | called by muse, mutect2, varscan2
- CDK5RAP2 | c.1731C>T p.I577= | Silent (SNP) | VAF 35/295 reads (12%) | called by muse, mutect2, varscan2
- HK3 | c.2160C>T p.D720= | Silent (SNP) | VAF 263/642 reads (41%) | catalogued as rs371103424; called by muse, mutect2, varscan2
- MCF2L | c.2529G>A p.K843= (on ENST00000375608; = p.K811= on NM_024979.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 192/477 reads (40%) | called by muse, mutect2, varscan2
- PCDHGB5 | c.1554C>T p.Y518= | Silent (SNP) | VAF 70/752 reads (9%) | called by muse, mutect2
- RAB40AL | c.309G>A p.E103= | Silent (SNP) | VAF 10/278 reads (4%) | called by muse, mutect2
- SCN4A | c.3150C>T p.F1050= | Silent (SNP) | VAF 21/279 reads (8%) | catalogued as rs536963836, COSV71125690; called by muse, mutect2
- SIK3 | c.1017G>A p.L339= (on ENST00000445177 / NM_001366686.2; = p.L345= on NM_025164.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 123/487 reads (25%) | called by muse, mutect2, varscan2
- SLCO5A1 | c.258G>A p.P86= | Silent (SNP) | VAF 50/655 reads (8%) | catalogued as rs777138818, COSV52657734; called by muse, mutect2
- ZNF317 | c.1281C>T p.F427= | Silent (SNP) | VAF 106/419 reads (25%) | catalogued as rs1417893397; called by muse, mutect2, varscan2
- ZNF501 | c.603G>A p.Q201= | Silent (SNP) | VAF 28/468 reads (6%) | called by muse, mutect2
- ZNF615 | c.1164C>T p.I388= | Silent (SNP) | VAF 30/312 reads (10%) | called by muse, mutect2, varscan2
- FOXJ2 | c.-1009C>T | 5'UTR (SNP) | VAF 293/806 reads (36%) | called by muse, mutect2, varscan2
- RAB11FIP3 | c.-186G>T | 5'UTR (SNP) | VAF 55/691 reads (8%) | called by muse, mutect2
